Somatic mutation profile of tumor specimen TCGA-BR-8291-01A (aliquot TCGA-BR-8291-01A-11D-2340-08) from TCGA case TCGA-BR-8291, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 61.7 years (22,552 days).
Specimen TCGA-BR-8291-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a08c4786-f24b-47fb-9a20-f5b6f4a1e1cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8291-10A (Blood Derived Normal), aliquot TCGA-BR-8291-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e33eb647-67bd-40f0-a2b1-00654f1a91e1

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Nonsense Mutation 3, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.3859T>C p.*1287Rext*? (on ENST00000265723 / NM_018849.3; = p.*1280Rext*19 on NM_000443.4) | Nonstop Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as rs754770911, CM133062, COSV55933045; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP12 | c.2440C>T p.R814* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as rs1562754144, COSV53575007; called by muse, mutect2, varscan2
- C2orf49 | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV51527793; called by muse, mutect2, varscan2
- CSMD1 | c.2354G>T p.C785F (on ENST00000520002; = p.C784F on NM_033225.6) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100146332; called by muse, mutect2
- EIF3C | c.969G>T p.E323D | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV59060325; called by muse, mutect2, varscan2
- FCRL3 | c.642G>C p.Q214H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); catalogued as COSV63841432, COSV63843885; called by muse, mutect2, varscan2
- NLRP2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs373538812; called by muse, mutect2, varscan2
- OR51B5 | c.547A>T p.I183F | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV56175987; called by muse, mutect2, varscan2
- PAH | c.576G>T p.K192N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV61016412; called by muse, mutect2, varscan2
- PRELID3B | c.53C>A p.T18K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.908); catalogued as rs760700006, COSV63505310; called by muse, mutect2, varscan2
- PTGES3 | c.131G>A p.S44N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV56273737; called by muse, mutect2
- PTPRB | c.5876G>A p.C1959Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54240321; called by muse, mutect2
- RSAD1 | c.1297C>T p.Q433* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV51955651; called by muse, mutect2, varscan2
- RYR1 | c.4240G>A p.V1414M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as rs376330174; called by muse, mutect2
- SOX5 | c.699A>C p.K233N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58629102; called by muse, mutect2, varscan2
- SPACA3 | c.433A>C p.I145L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.402); catalogued as COSV52191152; called by muse, mutect2, varscan2
- SPEG | c.2896C>T p.R966W | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs766307838, COSV56668634; called by muse, mutect2, varscan2
- TRIM69 | c.35A>G p.D12G | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); catalogued as rs1342787715, COSV57803801; called by muse, mutect2, varscan2
- UTP20 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779027623, COSV55376914; called by muse, mutect2, varscan2
- WNT10B | c.617G>C p.G206A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV56405360; called by muse, mutect2, varscan2
- ZNF461 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV64453653; called by muse, mutect2
- ZNF804B | c.3848T>G p.L1283R | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV60820425; called by muse, mutect2, varscan2
- ARID1A | c.2177_2189del p.P726Lfs*12 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel, varscan2
- ABCA9 | c.4413G>A p.E1471= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV60624737; called by muse, mutect2, varscan2
- ACTR8 | c.1816C>A p.R606= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV99213657; called by muse, mutect2
- ATP11A | c.294T>C p.L98= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV52111400; called by muse, mutect2
- ATP7A | c.4017G>A p.L1339= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV58446240; called by muse, mutect2, varscan2
- OPCML | c.987T>C p.A329= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV59409651, COSV59428469; called by muse, mutect2, varscan2
- SAMD9L | c.2440C>T p.L814= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV100560672; called by muse, mutect2
- TSSK6 | c.420C>T p.N140= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1312634250, COSV53063661; called by muse, mutect2, varscan2
